Surgical pathology report (de-identified scan), TCGA case TCGA-AH-6644, project TCGA-READ (Rectum Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-AH-6644-01A (Primary Tumor).

[page 1 of 2]
QC Pathologist:

*** ADDENDUM REPORT ***

Addendum Final Diagnosis:

Two additional lymph nodes are identified in the gross specimen. No malignancy is identified.

Addendum Gross Description:

Per the request of the surgeon, the specimen is re-examined in search for additional lymph nodes. The mesenteric fat is placed in lymph node Revealing Solution. Upon fixation there reveals two additional possible lymph nodes that measure 0.3 and 0.5 cm in greatest dimension. Each of the lymph nodes have been bisected and submitted in cassette A14

Addendum Report Issued By:

FINAL PATHOLOGIC DIAGNOSIS:

A. Rectosigmoid colon, partial colectomy:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Histologic grade: Well differentiated.
3. Tumor site: Rectosigmoid colon.
4. Tumor size: Circumferential 3.5 x 3.0 cm tumor.
5. Lymphovascular space invasion: No.
6. Microscopic tumor extension:
- a. Tumor extends through the entire thickness of the muscularis propria.

Surgical Margin Status:

1. Proximal margin: Negative.
2. Circumferential margin: Negative.
3. Distal margin: Negative.
4. Closest tumor margin: 3 cm from the distal margin.

Lymph Node Status:

1. Thirteen lymph nodes negative for metastatic carcinoma.

Other:

1. pTNM stage: T3.

B. Sigmoid colon rings:

Colonic mucosa negative for malignancy.

[page 2 of 2]
COMMENTS:

CLINICAL HISTORY:

Preoperative Diagnosis: Cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Rectosigmoid colon

B. Sigmoid colon rings

PROCEDURAL DEMOGRAPHICS:

Date of Procedure:

Accession Date/Time:

GROSS DESCRIPTION:

A. The first container A is labeled with the patient's name

The specimen consists of a segment of rectosigmoid colon measuring 14 cm in total length and up to 2 cm in diameter. The proximal margin is open. The distal margin is stapled. The serosal surface of the bowel is gray to brown-tan with hemorrhage. The attached mesentery is yellow to brown-tan also displaying hemorrhage. On opening the bowel the mucosal surface is light tan. There is a circumferential brown-tan nodular mass, 3.5 x 3.0 cm that is 3.7 cm from the distal margin and 6.2 cm from the proximal margin. On sectioning the mass it extends into the underlying bowel wall, but does not grossly penetrate through the serosa and is 1.5 cm from the deep resected margin. The surrounding colon is gray-tan and reveals normal folds. On sectioning through the mesentery there are 17 probable lymph nodes that measure from 0.2 up to 0.7 cm. Received with the specimen are two cassettes, one gray and one yellow labeled [REDACTED]. Representative sections are submitted in cassettes labeled [REDACTED] as follows: proximal margin block 1; distal margin block 2; sections from mass in blocks 3-7; surrounding uninvolved colon block 8; lymph nodes submitted in total as follows: six probable nodes block 9; four probable nodes block 10; one probable node bisected in block 11; two probable nodes each bisected in block 12; four probable nodes in block 13.

B. The second container B is labeled with the [REDACTED] sigmoid colon rings. The specimen consists of two circular fragments of bowel measuring 2.0 x 1.5 x 1.0 and 2.0 x 1.5 x 1.5 cm. The mucosal surfaces are brown-tan with slight hemorrhage. Representative section from each piece is taken and is submitted in a single cassette labeled [REDACTED]

Source: NCI Genomic Data Commons file f8e1b228-acb9-488b-b535-2df2bac4ac46 (TCGA-AH-6644.D7D2D0D8-C704-4033-897C-167D7BD1BDA6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).